Gene-level copy-number profile of tumor specimen HTMCP-01-06-00185-01A from CGCI case HTMCP-01-06-00185, project CGCI-HTMCP-DLBCL (HIV+ Tumor Molecular Characterization Project - Diffuse Large B-Cell Lymphoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Diffuse large B-cell lymphoma, NOS; Tissue or organ of origin: Hematopoietic system, NOS; Age at diagnosis: 71.8 years (26,233 days).
Specimen HTMCP-01-06-00185-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 4f0b2798-d72a-4219-a565-7195949329a3.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HTMCP-01-06-00185-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,221 have no estimate.
https://portal.gdc.cancer.gov/files/3b66e84d-0dd5-4e48-9413-fe7add5fa6a4

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 13; copy number 1: 4,401; copy number 2: 43,223; copy number 3: 8,371; copy number 4: 907; copy number 5: 881; copy number 6: 423; copy number 7: 28; copy number 8: 1; copy number 9: 8; copy number 10: 45; copy number 11: 22; copy number 14: 5; copy number 16: 2; copy number 18: 6; copy number 19: 18; copy number 21: 3; copy number 27: 45.

Homozygous deletions (total copy number 0; autosomes only): 13 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:232,727,251–232,808,407, 2 genes: LINC01744, MAP10.
- chr6:29,926,459–29,945,884, 4 genes (within-gene range 0–2): HLA-K, HLA-U, HLA-A, AL671277.1.
- chr9:2,421,597–2,844,095, 6 genes: VLDLR-AS1, AL353614.1, VLDLR, AL450467.1, KCNV2, PUM3.
- chr14:105,721,794–105,722,527, 1 gene (within-gene range 0–1): IGHEP1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,487 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:4,814,294–5,256,761, 14 genes, copy number 5 (within-gene range 1–5): AC018816.1, BHLHE40-AS1, BHLHE40, RNF10P1, UBTFL8, Y_RNA, AC090955.1, ARL8B, AC026202.2, AC026202.3, EDEM1, MIR4790, RN7SL553P, AC026202.1.
- chr3:122,909,082–126,960,420, 88 genes, copy number 5–10 (within-gene range 3–10) (broad region; genes not listed).
- chr3:136,205,540–137,011,085, 16 genes, copy number 6–10: AC092991.1, PCCB, STAG1, RNU6-1284P, HMGN1P10, RNU6-789P, AC117382.1, AC117382.2, AC096992.1, SLC35G2, NCK1-DT, AC096992.2, NCK1, RAD51AP1P1, IL20RB, IL20RB-AS1.
- chr3:174,302,944–198,123,232, 487 genes, copy number 5–27 (broad region; genes not listed).
- chr8:614,746–1,708,476, 8 genes, copy number 5–8 (within-gene range 2–8): ERICH1, AC100797.1, DLGAP2, AC100797.4, AC026950.2, AC129915.3, AC110288.1, AF067845.2.
- chr11:90,085,950–100,358,885, 144 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr11:100,336,856–134,986,799, 730 genes, copy number 5–6 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 3,098. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
